Surgical pathology report (de-identified scan), TCGA case TCGA-PL-A8LZ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Institute of Human Virology Nigeria, specimen TCGA-PL-A8LZ-01A (Primary Tumor).

[page 1 of 2]
Age:

Sex: Female

Tissue Source Site (TSS):

Date of Tumour Procurement:

ICD-O-3
Carcinoma, infiltrating duct NOS
Site: @ Breast NOS
8500/3
C50.9
p2 5/19/14

1. **GROSS ASSESSMENT:** Cut section showed a chalky white tumour. 4x3x2cm,

2. MICROSCOPIC ASSESSMENT

Microscopic description: Section shows an invasive tumour growing in solid nests and tubular patterns. It is composed of cells having moderately pleomorphic hyperchromatic nuclei and amphophilic cytoplasm. The stroma is desmoplastic containing thin-walled vascular channels, tumour cells and lymphocytes. Focal areas of necrosis noted,

3. **Tumour Type:** Malignant

4. **Tumour Site:** Left Breast

5. **Distance of invasive carcinoma to closest margin:** 5mm

- **Which margin?** Deep resection

[page 2 of 2]
TSS Unique patient ID:

6. **HISTOLOGICAL DIAGNOSIS:** Invasive ductal carcinoma, NOS

7. **COMMENTS:** nil

Dr

Reporting Pathologist Name

Signature

Date

Criteria	11/14/13	Yes	No
HIP Site Discrepancy			✓
Metastatic/Synchronous Primary Cited			

Source: NCI Genomic Data Commons file 5f48465f-5ab3-4b0d-bf2f-b917c6567d13 (TCGA-PL-A8LZ.436F3280-98C7-4FA9-BD6F-1B02CAF1D262.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).